Gene-level copy-number profile of tumor specimen ALCH-B1LS-TTP1-A from ALCHEMIST case ALCH-B1LS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.4 years (22,784 days).
Specimen ALCH-B1LS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 117f1cd4-9ed3-471f-ad30-1e5bc13e683a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1LS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/7296ae1d-60cc-4ec6-8908-7d9693f87f6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 4,380; copy number 2: 52,007; copy number 3: 1,570; copy number 4: 371; copy number 5: 1; copy number 6: 3; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,578,478–91,621,421, 3 genes (within-gene range 0–2): AC233266.1, AC233266.2, AC116050.1.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr3:130,089,433–130,094,304, 1 gene (within-gene range 0–1): LINC02014.
- chr7:127,997,597–128,081,960, 3 genes (within-gene range 0–2): SND1-IT1, LRRC4, MIR593.
- chr8:22,089,150–22,104,911, 1 gene: FAM160B2.
- chr9:88,534,033–88,584,274, 1 gene: NXNL2.
- chr9:121,519,816–121,520,424, 1 gene: HMGB1P37.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–1): AL357936.1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:124,853,417–124,861,981, 2 genes: WDR38, RPL35.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr15:25,172,635–25,225,284, 29 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:73,319,859–73,368,958, 2 genes (within-gene range 0–2): HCN4, AC068397.2.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,615,515–170,738,536, 1 gene, copy number 11 (within-gene range 3–11): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 11: AL731684.1.
- chr7:56,940,341–56,944,353, 1 gene, copy number 5: AC069152.1.
- chr22:20,338,805–20,354,387, 3 genes, copy number 6 (within-gene range 4–6): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 4,342. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
